Somatic mutation profile of tumor specimen TCGA-AR-A1AW-01A (aliquot TCGA-AR-A1AW-01A-21D-A12Q-09) from TCGA case TCGA-AR-A1AW, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 65.3 years (23,855 days).
Specimen TCGA-AR-A1AW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b44b6fdc-0e8e-4ece-9322-56024b0f13e4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AR-A1AW-10A (Blood Derived Normal), aliquot TCGA-AR-A1AW-10A-01D-A12Q-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d76f1fa8-b280-4767-8d79-ea06be1ac9dd

The open-access MAF lists 38 somatic variants for this specimen: 28 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 24, Silent 10, Nonsense Mutation 3, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.4341G>C p.Q1447H (on ENST00000358273 / NM_001042492.3; = p.Q1426H on NM_000267.3) | Missense Mutation (SNP) | VAF 63/241 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as rs876660206, CD1311343, CM143402, COSV62198273, COSV62211384; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 38/201 reads (19%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 75/206 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADGRG4 | c.6041T>C p.L2014P | Missense Mutation (SNP) | VAF 13/257 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.84); catalogued as rs1390620474, COSV99795848; called by muse, mutect2
- APBA1 | c.1682G>A p.R561Q | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs370688256; called by muse, mutect2, varscan2
- BCO1 | c.849T>A p.Y283* | Nonsense Mutation (SNP) | VAF 12/95 reads (13%) | catalogued as COSV50728747; called by muse, mutect2, varscan2
- BRPF1 | c.1796A>C p.E599A | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV57404038; called by muse, mutect2, varscan2
- CACNA1E | c.2002C>T p.R668C | Missense Mutation (SNP) | VAF 12/366 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1228711500, COSV62412279; called by muse, mutect2
- DNAJC8 | c.595C>T p.Q199* | Nonsense Mutation (SNP) | VAF 24/653 reads (4%) | catalogued as COSV99746365; called by muse, mutect2
- ELOVL5 | c.208C>T p.L70F | Missense Mutation (SNP) | VAF 26/211 reads (12%) | SIFT tolerated (0.56); PolyPhen benign (0.116); catalogued as COSV58649586; called by mutect2, varscan2
- GNAS | c.853A>G p.I285V | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.044); catalogued as COSV55673710; called by muse, mutect2, varscan2
- GRID2 | c.2285G>T p.G762V | Missense Mutation (SNP) | VAF 30/489 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.49); catalogued as rs1450154666, COSV99942256; called by muse, mutect2
- IGSF10 | c.5245G>A p.E1749K | Missense Mutation (SNP) | VAF 11/109 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.627); catalogued as COSV56783868; called by muse, mutect2, varscan2
- KCNJ16 | c.231T>G p.F77L | Missense Mutation (SNP) | VAF 43/634 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV99388420; called by muse, mutect2
- LILRA1 | c.710C>T p.A237V | Missense Mutation (SNP) | VAF 59/344 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.314); catalogued as rs1419778295, COSV52179527; called by muse, varscan2
- MAP3K10 | c.922G>T p.A308S | Missense Mutation (SNP) | VAF 3/53 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.195); catalogued as COSV53425075, COSV99454522; called by muse, mutect2
- MPZL1 | c.436C>T p.Q146* | Nonsense Mutation (SNP) | VAF 31/231 reads (13%) | catalogued as COSV63256187; called by muse, mutect2, varscan2
- PCDH19 | c.856C>T p.R286C | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV55257022; called by muse, mutect2, varscan2
- PHF6 | c.982A>T p.N328Y | Missense Mutation (SNP) | VAF 58/366 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV59700859; called by muse, mutect2, varscan2
- PRKCB | c.1007G>A p.R336Q | Missense Mutation (SNP) | VAF 11/275 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as rs1163412779, COSV57768797, COSV57799135; called by muse, mutect2
- RASAL2 | c.599G>A p.R200H | Missense Mutation (SNP) | VAF 55/212 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750108608, COSV62711841; called by muse, mutect2, varscan2
- SHLD1 | c.542A>C p.D181A | Missense Mutation (SNP) | VAF 14/270 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.027); catalogued as COSV100290513; called by muse, mutect2
- SOCS4 | c.269C>A p.S90Y | Missense Mutation (SNP) | VAF 20/160 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV59460237; called by muse, mutect2, varscan2
- SYTL4 | c.1549C>T p.R517W | Missense Mutation (SNP) | VAF 24/184 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV52165391, COSV99343165; called by muse, mutect2, varscan2
- TRANK1 | c.5359G>T p.A1787S | Missense Mutation (SNP) | VAF 25/159 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.876); catalogued as COSV57145670, COSV57145991; called by muse, mutect2, varscan2
- ZBTB2 | c.233A>G p.H78R | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as COSV100287721; called by muse, mutect2
- BAHCC1 | c.3957del p.S1322Afs*42 | Frame Shift Del (DEL) | VAF 7/32 reads (22%) | called by mutect2, varscan2
- SCN3A | c.5224G>T p.G1742W | Missense Mutation (SNP) | VAF 14/367 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CATSPERD | c.216T>C p.F72= | Silent (SNP) | VAF 50/570 reads (9%) | catalogued as rs1289187995, COSV101062436; called by muse, mutect2
- CD200R1L | c.648C>T p.G216= | Silent (SNP) | VAF 5/58 reads (9%) | catalogued as COSV101236603; called by muse, mutect2
- CLUL1 | c.24T>C p.F8= | Silent (SNP) | VAF 19/181 reads (10%) | catalogued as rs771767873, COSV100620998; called by muse, mutect2
- HMCN1 | c.15075C>A p.T5025= | Silent (SNP) | VAF 11/203 reads (5%) | catalogued as COSV99630833; called by muse, mutect2
- MAGEA11 | c.1170C>G p.A390= | Silent (SNP) | VAF 9/87 reads (10%) | catalogued as COSV60754717; called by muse, varscan2
- MUC16 | c.39462C>T p.S13154= | Silent (SNP) | VAF 47/398 reads (12%) | catalogued as rs1396203877, COSV66690904; called by muse, mutect2, varscan2
- NFKB2 | c.1137C>T p.F379= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as rs920445238; called by muse, mutect2
- RYR2 | c.2388A>T p.A796= | Silent (SNP) | VAF 34/636 reads (5%) | catalogued as COSV100771158; called by muse, mutect2
- ZNF613 | c.1824C>T p.V608= (on ENST00000293471 / NM_001031721.4; = p.V572= on NM_024840.4) | Silent (SNP) | VAF 8/74 reads (11%) | catalogued as rs868793836, COSV99522984; called by muse, mutect2
- ZNF831 | c.3351G>A p.G1117= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as COSV100926090; called by muse, mutect2
